CCDI case PBCHBP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f3373307-ec1f-4e64-9ec0-6e06a463c305

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ewing sarcoma: ICD-O-3 morphology code: 9364/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.6 years (967 days).

Biospecimens (3 samples)
- Sample 0DRSRX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRSSD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRSU0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
